Somatic mutation profile of tumor specimen TARGET-10-PARMMV-09A (aliquot TARGET-10-PARMMV-09A-01D) from TARGET case TARGET-10-PARMMV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.4 years (2,322 days).
Specimen TARGET-10-PARMMV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9babce7a-ffd6-45ff-afa6-c454617756c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARMMV-14A (Bone Marrow Normal), aliquot TARGET-10-PARMMV-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41d594d4-7cfb-4664-a288-7ca88621e6e1

The open-access MAF lists 17 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 5, Intron 2, Nonsense Mutation 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 22/148 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, varscan2
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 44/138 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, varscan2
- GRIK3 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as rs769854366, COSV66142993; called by muse, mutect2, varscan2
- GSG1L | c.745C>T p.R249W (on ENST00000447459 / NM_001109763.2; = p.R94W on NM_144675.2) | Missense Mutation (SNP) | VAF 65/134 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs752444585, COSV66576706; called by muse, mutect2, varscan2
- NOTCH1 | c.4793G>C p.R1598P | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.918); catalogued as COSV53027279, COSV53097635; called by muse, varscan2
- SLC46A2 | c.1174C>T p.R392* | Nonsense Mutation (SNP) | VAF 22/57 reads (39%) | catalogued as rs1364383096, COSV65290208; called by muse, mutect2, varscan2
- SPTSSB | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs375216413; called by muse, mutect2, varscan2
- TBX21 | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.092); catalogued as COSV51597215; called by muse, mutect2, varscan2
- ERG | c.907_908insATCAAGGT p.L303Hfs*49 (on ENST00000398919 / NM_001243428.1; = p.L279Hfs*49 on NM_004449.4) | Frame Shift Ins (INS) | VAF 33/84 reads (39%) | called by mutect2, pindel*, varscan2*
- GREB1L | c.2652C>T p.D884= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as rs369012735; called by muse, mutect2, varscan2
- PCDHA7 | c.171G>A p.A57= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV65343648; called by muse, mutect2, varscan2
- PGAP4 | c.1104G>A p.S368= | Silent (SNP) | VAF 51/116 reads (44%) | catalogued as rs747784678; called by muse, mutect2, varscan2
- RC3H2 | c.2550C>T p.A850= | Silent (SNP) | VAF 92/208 reads (44%) | called by muse, mutect2, varscan2
- UCP2 | c.708C>T p.D236= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as rs764796915, COSV60104362; called by mutect2, varscan2
- ADCY4 | c.1058+12C>T | Intron (SNP) | VAF 13/28 reads (46%) | catalogued as rs373387300; called by muse, mutect2, varscan2
- CHD9 | c.-164-34520T>C | Intron (SNP) | VAF 79/187 reads (42%) | called by muse, mutect2, varscan2
- SSTR2 | c.*299dup | 3'UTR (INS) | VAF 23/68 reads (34%) | catalogued as rs1302515511; called by mutect2, varscan2
